Somatic mutation profile of tumor specimen TCGA-13-0890-01A (aliquot TCGA-13-0890-01A-01W-0420-08) from TCGA case TCGA-13-0890, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 56.9 years (20,770 days).
Specimen TCGA-13-0890-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fd9a7bcf-aa8f-4981-b490-838b27d6700f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0890-10A (Blood Derived Normal), aliquot TCGA-13-0890-10A-01W-0420-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a96fb14d-5a6b-4e68-bea7-bd6c075c358a

The open-access MAF lists 70 somatic variants for this specimen: 57 protein-altering or splice-affecting, 12 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 12, Frame Shift Del 3, Frame Shift Ins 2, Splice Site 2, In Frame Del 2, RNA 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRCA2 | c.3688del p.S1230Lfs*9 | Frame Shift Del (DEL) | VAF 45/125 reads (36%) | catalogued as rs878853573; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ADAMTS20 | c.1625A>C p.H542P | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV67136986; called by muse, mutect2, varscan2
- ADCK1 | c.528G>T p.K176N | Missense Mutation (SNP) | VAF 32/480 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99451537; called by muse, mutect2
- AKAP1 | c.2444T>A p.V815D | Missense Mutation (SNP) | VAF 143/616 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61805791; called by muse, mutect2, varscan2
- ALDH1L1 | c.295dup p.R99Pfs*14 | Frame Shift Ins (INS) | VAF 5/46 reads (11%) | catalogued as rs755422577; called by mutect2, pindel
- ARHGEF10 | c.567A>C p.E189D (on ENST00000398564; = p.E164D on NM_014629.4) | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.081); catalogued as COSV50668023; called by muse, mutect2, varscan2
- ARHGEF15 | c.2261A>G p.E754G | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.874); catalogued as COSV62726022; called by muse, mutect2, varscan2
- ATP2A1 | c.1141G>A p.E381K | Missense Mutation (SNP) | VAF 74/248 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs768227607, COSV63921956; called by muse, mutect2, varscan2
- AWAT1 | c.254C>T p.T85M | Missense Mutation (SNP) | VAF 62/694 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as rs1193140346, COSV65738124, COSV65738782; called by muse, mutect2
- BCORL1 | c.400A>T p.N134Y | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.042); catalogued as COSV54403715; called by muse, mutect2, varscan2
- BOLL | c.499T>G p.S167A | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.116); catalogued as COSV56576481; called by muse, mutect2, varscan2
- CBLIF | c.457A>T p.I153L | Missense Mutation (SNP) | VAF 168/455 reads (37%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV57240038; called by muse, mutect2, varscan2
- CCER1 | c.424C>T p.R142C | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.112); catalogued as rs748776182, COSV62648591; called by muse, mutect2, varscan2
- CEP19 | c.140G>C p.R47T | Missense Mutation (SNP) | VAF 9/128 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.463); catalogued as COSV99582408; called by muse, mutect2
- CLTRN | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.104); catalogued as COSV66712311; called by muse, mutect2, varscan2
- EMSY | c.787T>C p.F263L | Missense Mutation (SNP) | VAF 97/304 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV58264459; called by muse, mutect2, varscan2
- FBH1 | c.1732A>T p.I578F (on ENST00000362091 / NM_178150.3; = p.I629F on NM_032807.4) | Missense Mutation (SNP) | VAF 119/271 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as rs765708557, COSV62984030; called by muse, mutect2, varscan2
- GPR149 | c.802T>G p.S268A | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated (0.42); PolyPhen benign (0.007); catalogued as COSV67669180; called by muse, mutect2, varscan2
- HRH4 | c.1073A>T p.Y358F | Missense Mutation (SNP) | VAF 142/542 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56929293; called by muse, mutect2, varscan2
- IFT172 | c.104C>T p.T35I | Missense Mutation (SNP) | VAF 154/541 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53137398; called by muse, mutect2, varscan2
- IGF2R | c.5845C>G p.R1949G | Missense Mutation (SNP) | VAF 70/205 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.314); catalogued as COSV63631737; called by muse, mutect2, varscan2
- INPP5F | c.3163G>T p.V1055L | Missense Mutation (SNP) | VAF 92/419 reads (22%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as COSV62823063; called by muse, mutect2, varscan2
- KIF17 | c.378G>T p.Q126H | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.62); catalogued as COSV99928919; called by muse, mutect2, varscan2
- KSR2 | c.616G>A p.V206I | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs779209250, COSV100348449, COSV60399516; called by muse, mutect2, varscan2
- LAMP3 | c.760-1G>C p.X254_splice | Splice Site (SNP) | VAF 183/607 reads (30%) | catalogued as COSV55616431; called by muse, mutect2, varscan2
- LYN | c.907G>C p.V303L | Missense Mutation (SNP) | VAF 95/520 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.208); catalogued as COSV101319621, COSV70206227; called by muse, mutect2, varscan2
- MTHFD1L | c.2247G>C p.M749I | Missense Mutation (SNP) | VAF 51/145 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66226845; called by muse, mutect2, varscan2
- MTMR12 | c.1132G>C p.E378Q | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.98); catalogued as COSV53782768, COSV53786660; called by muse, mutect2, varscan2
- MUC3A | c.8254C>A p.L2752I | Missense Mutation (SNP) | VAF 62/437 reads (14%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.334); catalogued as rs746970474, COSV60222445; called by muse, mutect2
- NCOA3 | c.3593C>G p.P1198R | Missense Mutation (SNP) | VAF 85/329 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV59071851; called by muse, mutect2, varscan2
- NUP210L | c.2804A>C p.Q935P | Missense Mutation (SNP) | VAF 101/471 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.374); catalogued as rs1266744764, COSV55154655; called by muse, mutect2, varscan2
- OBSCN | c.3574C>G p.Q1192E | Missense Mutation (SNP) | VAF 76/387 reads (20%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.6); catalogued as COSV52811895, COSV99472103; called by muse, mutect2, varscan2
- OVGP1 | c.70C>G p.L24V | Missense Mutation (SNP) | VAF 77/184 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV63859678; called by muse, mutect2, varscan2
- PHF21B | c.266A>C p.D89A | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.37); catalogued as rs781571122, COSV57560962; called by muse, mutect2, varscan2
- PPEF2 | c.436G>A p.V146I | Missense Mutation (SNP) | VAF 35/336 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.954); catalogued as rs186986454, COSV99714455; called by mutect2, varscan2
- PRC1 | c.1403C>G p.P468R | Missense Mutation (SNP) | VAF 156/468 reads (33%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.93); catalogued as COSV62695062, COSV62696276; called by muse, mutect2, varscan2
- RELCH | c.869T>G p.L290* | Nonsense Mutation (SNP) | VAF 17/31 reads (55%) | catalogued as COSV56890141; called by muse, mutect2, varscan2
- SENP6 | c.890C>G p.T297S | Missense Mutation (SNP) | VAF 46/101 reads (46%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59193354; called by muse, mutect2, varscan2
- SIK3 | c.2301A>C p.L767F (on ENST00000445177 / NM_001366686.2; = p.L725F on NM_025164.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 99/313 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.654); catalogued as COSV52621236; called by mutect2, varscan2
- SLC12A8 | c.2133G>C p.M711I | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.02); catalogued as COSV100102242; called by muse, mutect2, varscan2
- SORBS2 | c.2816A>G p.E939G (on ENST00000284776 / NM_021069.5; = p.E505G on NM_003603.6) | Missense Mutation (SNP) | VAF 73/189 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV53010991; called by muse, mutect2, varscan2
- SPOCD1 | c.2819C>A p.T940N | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); catalogued as COSV99929761; called by muse, mutect2, varscan2
- STAB2 | c.155T>A p.V52D | Missense Mutation (SNP) | VAF 150/498 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.133); catalogued as COSV66344495; called by muse, mutect2, varscan2
- STAT3 | c.1490C>T p.P497L | Missense Mutation (SNP) | VAF 38/266 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99232699; called by mutect2, varscan2
- SYT17 | c.568T>G p.F190V | Missense Mutation (SNP) | VAF 180/460 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV62547629; called by muse, mutect2, varscan2
- TAF1 | c.4188C>G p.D1396E (on ENST00000373790 / NM_138923.4; = p.D1417E on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 222/766 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV52121784; called by muse, mutect2, varscan2
- TBC1D5 | c.1430G>C p.S477T | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.051); catalogued as COSV53766783, COSV99511835; called by muse, mutect2, varscan2
- TENM2 | c.2688G>T p.W896C (on ENST00000518659 / NM_001122679.2; = p.W664C on NM_001080428.3) | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV69138171, COSV69143831; called by muse, mutect2, varscan2
- TNIK | c.1371G>T p.Q457H | Missense Mutation (SNP) | VAF 144/791 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs916652428, COSV52691601; called by mutect2, varscan2
- TSR1 | c.1152G>C p.K384N | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV52160733; called by muse, mutect2, varscan2
- UMPS | c.75C>G p.D25E | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99228945; called by muse, mutect2, varscan2
- WAC | c.1437+1G>T p.X479_splice | Splice Site (SNP) | VAF 46/286 reads (16%) | catalogued as COSV100610959, COSV61569127, COSV61569197; called by muse, mutect2, varscan2
- CSTF3 | c.302_312del p.W101Sfs*10 | Frame Shift Del (DEL) | VAF 20/112 reads (18%) | called by mutect2, pindel, varscan2
- EVC2 | c.1906_1917del p.D636_E639del | In Frame Del (DEL) | VAF 24/153 reads (16%) | called by pindel, varscan2
- GLP2R | c.454_465del p.I152_D155del | In Frame Del (DEL) | VAF 60/406 reads (15%) | called by mutect2, pindel
- MTCL1 | c.1316_1322del p.L439Rfs*20 (on ENST00000306329 / NM_001378206.1; = p.L79Rfs*20 on NM_015210.4) | Frame Shift Del (DEL) | VAF 90/414 reads (22%) | called by mutect2, pindel, varscan2
- PLEKHH3 | c.574dup p.V192Gfs*48 | Frame Shift Ins (INS) | VAF 5/47 reads (11%) | called by pindel, varscan2
- AURKA | c.795A>G p.G265= | Silent (SNP) | VAF 73/291 reads (25%) | catalogued as COSV57169717; called by muse, mutect2, varscan2
- DCTN1 | c.1356G>A p.E452= | Silent (SNP) | VAF 107/1021 reads (10%) | catalogued as rs200138600, COSV100720923; called by muse, mutect2, varscan2
- GIT1 | c.1626C>T p.D542= | Silent (SNP) | VAF 11/43 reads (26%) | catalogued as COSV99838146; called by muse, mutect2, varscan2
- GOLGA6L9 | c.1053G>C p.L351= | Silent (SNP) | VAF 10/91 reads (11%) | called by muse, mutect2, varscan2
- MYT1 | c.1509G>A p.T503= | Silent (SNP) | VAF 157/474 reads (33%) | catalogued as rs775580157, COSV60511211; called by muse, varscan2
- NUP210L | c.1200A>G p.T400= | Silent (SNP) | VAF 87/475 reads (18%) | catalogued as COSV55154670; called by muse, mutect2, varscan2
- OR8B4 | c.441C>G p.S147= | Silent (SNP) | VAF 29/262 reads (11%) | catalogued as COSV100635803; called by muse, mutect2, varscan2
- PIK3CA | c.1530C>T p.H510= | Silent (SNP) | VAF 80/303 reads (26%) | catalogued as rs200934230, COSV55946740; ClinVar: likely benign; called by muse, mutect2, varscan2
- PTH | c.330T>C p.T110= | Silent (SNP) | VAF 37/124 reads (30%) | catalogued as COSV56378833; called by muse, mutect2, varscan2
- SIX5 | c.718C>T p.L240= | Silent (SNP) | VAF 15/23 reads (65%) | catalogued as rs750553842, COSV52181200; called by muse, mutect2, varscan2
- STAG3 | c.1323C>A p.A441= | Silent (SNP) | VAF 95/341 reads (28%) | catalogued as COSV57933710; called by muse, mutect2, varscan2
- VRTN | c.2022C>T p.F674= | Silent (SNP) | VAF 14/294 reads (5%) | catalogued as COSV56441042; called by muse, mutect2
- OR2W5 | n.639C>A | RNA (SNP) | VAF 61/292 reads (21%) | called by muse, mutect2, varscan2
